Gene-level copy-number profile of specimen HCM-BROD-0579-C16-85M from HCMI case HCM-BROD-0579-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 36.9 years (13,485 days).
Specimen HCM-BROD-0579-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file acbe6bd0-c976-4aaf-ab11-94c14efca966.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0579-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/5eb76a85-5a2f-40f9-baea-3e266c127e13

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 114; copy number 2: 4,412; copy number 3: 31,190; copy number 4: 15,781; copy number 5: 2,495; copy number 6: 3,490; copy number 7: 311; copy number 8: 9; copy number 9: 116; copy number 10: 9; copy number 11: 59; copy number 12: 59; copy number 13: 29; copy number 14: 33; copy number 15: 29; copy number 16: 12; copy number 17: 28; copy number 21: 2; copy number 22: 14; copy number 23: 9; copy number 24: 7; copy number 26: 43; copy number 28: 4; copy number 32: 62; copy number 33: 1; copy number 34: 27; copy number 35: 4; copy number 37: 10; copy number 43: 23.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–91,112,790, 2 genes (within-gene range 0–3): TMSB4XP8, AC004054.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 900 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:230,592,660–231,118,325, 20 genes, copy number 7: LINC01737, AL158214.1, COG2, AL158214.2, AGT, AL512328.1, CAPN9, RNA5SP79, AL118511.2, C1orf198, AL118511.1, AL118511.4, AL118511.3, RN7SL837P, TTC13, ARV1, FAM89A, MIR1182, AL732414.1, AL109810.1.
- chr2:17,816,460–20,352,234, 32 genes, copy number 8–17: MSGN1, KCNS3, AC079802.1, AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P, AC106053.1, LINC01376, MIR4757, OSR1, AC010096.1, LINC01808, AC019055.1, CISD1P1, LINC00954, TTC32, AC013400.1, WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2.
- chr2:24,491,914–24,770,702, 1 gene, copy number 9 (within-gene range 5–9): NCOA1.
- chr2:24,676,309–27,159,229, 71 genes, copy number 9 (broad region; genes not listed).
- chr2:53,864,069–58,241,686, 59 genes, copy number 7: PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63, EIF2S2P7, AC068276.1, AC073875.1, ACTG1P22, VRK2, AC068193.1, FANCL, AC007250.1.
- chr2:58,427,799–59,063,766, 1 gene, copy number 7 (within-gene range 4–7): LINC01122.
- chr2:59,014,354–59,279,400, 2 genes, copy number 7 (within-gene range 6–7): AC007092.1, LINC01793.
- chr2:59,238,703–59,733,396, 3 genes, copy number 7 (within-gene range 6–7): AC007179.2, AC007179.1, AC007179.3.
- chr2:95,145,000–95,259,774, 4 genes, copy number 7 (within-gene range 4–7): ZNF514, ZNF2, SLC2AXP1, AC092835.1.
- chr7:83,955,777–99,638,767, 231 genes, copy number 13–43 (broad region; genes not listed).
- chr7:101,815,904–105,522,271, 86 genes, copy number 9–13 (broad region; genes not listed).
- chr12:21,437,615–21,775,600, 11 genes, copy number 17: PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8.
- chr12:21,827,210–21,887,957, 2 genes, copy number 17 (within-gene range 3–17): AC008250.1, AC008250.2.
- chr12:25,004,342–25,250,936, 9 genes, copy number 15 (within-gene range 3–15): IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:29,500,840–29,784,759, 1 gene, copy number 17 (within-gene range 3–17): TMTC1.
- chr12:29,658,376–29,658,798, 1 gene, copy number 17: RPL21P99.
- chr12:37,575,587–48,765,790, 205 genes, copy number 7–12 (broad region; genes not listed).
- chr12:56,271,699–56,488,414, 19 genes, copy number 15: CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2.
- chr12:73,648,666–73,846,188, 4 genes, copy number 14: AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:73,906,940–74,049,981, 2 genes, copy number 14–15: AC136188.1, LINC02394.
- chr12:79,690,144–80,029,631, 8 genes, copy number 17 (within-gene range 3–17): AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38.
- chr12:112,907,628–113,098,028, 6 genes, copy number 12 (within-gene range 3–12): AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1.
- chr16:34,941,977–47,971,693, 122 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 108. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
